Gene-level copy-number profile of tumor specimen HCM-SANG-0544-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0544-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0544-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b630761f-7652-4ce1-918c-4fc225c1b3fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0544-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/e0e891fe-6642-4821-b673-a681090b8aa5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1,817; copy number 2: 28,248; copy number 3: 19,278; copy number 4: 8,794; copy number 5: 772.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr2:186,590,056–186,765,959, 3 genes: ITGAV, AC017101.1, FAM171B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 769 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:38,258,409–38,465,480, 1 gene, copy number 5 (within-gene range 4–5): EGFLAM.
- chr5:38,399,814–41,880,210, 44 genes, copy number 5: EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1.
- chr5:44,066,624–45,098,647, 11 genes, copy number 5: RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1.
- chr20:35,285,251–64,327,972, 704 genes, copy number 5 (broad region; genes not listed).
- chr21:10,482,738–13,067,033, 9 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
